Gene-level copy-number profile of tumor specimen TCGA-AN-A0AL-01A from TCGA case TCGA-AN-A0AL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 41.9 years (15,286 days).
Specimen TCGA-AN-A0AL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.7076a7b9-6f06-4660-9fd9-3cbcc66bafda.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0AL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/96b89d0b-7ea4-4801-b344-96715d8bd7f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 17,636; copy number 2: 33,700; copy number 3: 6,683; copy number 4: 1,443; copy number 5: 152; copy number 6: 24; copy number 7: 42; copy number 8: 29; copy number 10: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0AL-01A-11D-A011-01): tumor purity 0.78, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,948,372–11,013,096, 2 genes: AL162413.1, AKAP8P1.
- chr9:21,165,637–26,892,803, 78 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 275 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:189,879,609–200,100,025, 124 genes, copy number 5–7 (broad region; genes not listed).
- chr3:181,505,075–182,740,848, 24 genes, copy number 6: RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2.
- chr12:752,579–2,004,535, 23 genes, copy number 5: WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B.
- chr12:2,004,666–2,049,463, 3 genes, copy number 5: AC005342.1, CACNA1C-IT1, CACNA1C-IT2.
- chr12:116,357,578–116,359,096, 1 gene, copy number 5: AC079384.2.
- chr15:98,038,571–98,293,199, 1 gene, copy number 5 (within-gene range 2–5): AC022523.1.
- chr15:98,282,075–101,933,350, 99 genes, copy number 5–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
